Somatic mutation profile of tumor specimen TARGET-20-PASZZL-09A (aliquot TARGET-20-PASZZL-09A-01D) from TARGET case TARGET-20-PASZZL, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,448 days).
Specimen TARGET-20-PASZZL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb2a8d81-d216-4110-8e33-954a70b97e37.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASZZL-14A (Bone Marrow Normal), aliquot TARGET-20-PASZZL-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb44b5b9-e558-4cd1-b440-8a128ac94952

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Splice Site 1, Frame Shift Del 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NCOR1 | c.1352+1G>C p.X451_splice | Splice Site (SNP) | VAF 65/97 reads (67%) | catalogued as COSV52003708; called by muse, mutect2, varscan2
- CEBPA | c.949_951dup p.L317dup | In Frame Ins (INS) | VAF 49/121 reads (40%) | called by mutect2, pindel, varscan2
- NCOR1 | c.829_836del p.E277Qfs*15 | Frame Shift Del (DEL) | VAF 16/123 reads (13%) | called by mutect2, pindel, varscan2
